Surgical pathology report (de-identified scan), TCGA case TCGA-CV-7437, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site MD Anderson Cancer Center, specimen TCGA-CV-7437-01A (Primary Tumor).

SUPPLEMENTAL REPORT

DIAGNOSIS:

(A) TOTAL LARYNGECTOMY:

Hyoid bone and thyroid cartilage, no invasion by tumor.

COMMENT: This supplemental report is issued to give the diagnosis on specimens requiring decalcification. This report does not change any of the diagnoses given on the previous report.

DIAGNOSIS

(A) TOTAL LARYNGECTOMY:

MODERATELY DIFFERENTIATED SQUAMOUS CARCINOMA OF LARYNX INVOLVING RIGHT SUPRAGLOTTIC REGION, BASE OF RIGHT SIDE OF EPIGLOTTIS, RIGHT FALSE VOCAL CORD AND FOCALLY RIGHT TRUE VOCAL CORD. (SEE COMMENT)

Margins of resection (mucosal, soft tissue, tracheal), free of tumor.

Hyoid bone and thyroid cartilage, diagnosis pending decalcification.

COMMENT

The squamous carcinoma measures 1.5 x 1.3 x 0.7 cm in greatest dimension. Focal perineural invasion and focal vascular channel invasion by tumor is identified.

SPECIMEN

(A) TOTAL LARYNGECTOMY:

SNOMED CODES

T-24100,M-80703

Source: NCI Genomic Data Commons file ce7fa43c-6376-4144-b200-a64f08ccd954 (TCGA-CV-7437.8D2C5741-ED13-4ABA-8A62-AD928F223D08.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).